Somatic mutation profile of tumor specimen TCGA-OR-A5LT-01A (aliquot TCGA-OR-A5LT-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LT, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 57.6 years (21,032 days).
Specimen TCGA-OR-A5LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 832ee88c-6b46-4632-8069-8a70ace3f30d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LT-10A (Blood Derived Normal), aliquot TCGA-OR-A5LT-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7e27d7-6701-47f0-9311-aaee0bba3b5a

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.249_252del p.I85Sfs*33 | Frame Shift Del (DEL) | VAF 67/75 reads (89%) | catalogued as rs587776841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRRIQ1 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 68/132 reads (52%) | catalogued as rs1382081755, COSV67830032; called by muse, mutect2, varscan2
- MORN5 | c.363C>G p.Y121* | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as COSV65648538; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- SAPCD2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs773327996; called by muse, mutect2, varscan2
- ATM | c.3032_3044del p.T1011Kfs*7 | Frame Shift Del (DEL) | VAF 60/68 reads (88%) | called by mutect2, pindel, varscan2
- DDX18 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DIAPH2 | c.2932T>C p.Y978H | Missense Mutation (SNP) | VAF 152/154 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- DPP10 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP11 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 154/331 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PGAP2 | c.666dup p.V223Cfs*28 (on ENST00000463452 / NM_001346398.2; = p.V284Cfs*28 on NM_014489.4) | Frame Shift Ins (INS) | VAF 119/174 reads (68%) | called by mutect2, pindel, varscan2
- ROBO1 | c.3583C>G p.P1195A | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, varscan2
- SCAF11 | c.538dup p.W180Lfs*19 | Frame Shift Ins (INS) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- SLC25A19 | c.288+1G>A p.X96_splice | Splice Site (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- SMC3 | c.2167A>G p.T723A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- WDR6 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZW10 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CDC42EP4 | c.594C>T p.Y198= | Silent (SNP) | VAF 77/169 reads (46%) | catalogued as rs776927898, COSV100231967; called by mutect2, varscan2
- POLA1 | c.3592C>T p.L1198= | Silent (SNP) | VAF 76/83 reads (92%) | catalogued as rs756064827; called by muse, mutect2, varscan2
